Somatic mutation profile of tumor specimen TCGA-56-A4ZK-01A (aliquot TCGA-56-A4ZK-01A-11D-A25L-08) from TCGA case TCGA-56-A4ZK, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.8 years (28,039 days).
Specimen TCGA-56-A4ZK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8b7b645-b082-4250-9b3c-1380d6509329.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-A4ZK-10A (Blood Derived Normal), aliquot TCGA-56-A4ZK-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b7e91f8-36eb-408b-a21d-95d6faf8c16f

The open-access MAF lists 242 somatic variants for this specimen: 184 protein-altering or splice-affecting, 45 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 159, Silent 45, Nonsense Mutation 13, Frame Shift Del 6, Intron 5, Splice Site 4, RNA 3, 5'UTR 2, 3'UTR 2, Frame Shift Ins 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R2 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372272045, COSV55846581, COSV55847676; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 37/70 reads (53%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2768G>T p.G923V | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100382564; called by muse, mutect2, varscan2
- ACOT4 | c.752C>G p.T251R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100412768; called by muse, varscan2
- ACOT4 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100412770; called by muse, varscan2
- ADAMTS5 | c.2528T>G p.L843* | Nonsense Mutation (SNP) | VAF 58/178 reads (33%) | catalogued as COSV99536961; called by muse, mutect2, varscan2
- ADAMTS8 | c.2021G>C p.R674P | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV57292852, COSV99960302; called by muse, mutect2, varscan2
- ADGRL1 | c.658G>A p.D220N (on ENST00000340736 / NM_001008701.3; = p.D215N on NM_014921.5) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100529236; called by muse, mutect2, varscan2
- AKAP11 | c.4405G>T p.A1469S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV99213428; called by muse, mutect2, varscan2
- ALDH1A1 | c.1131T>A p.N377K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99920987; called by muse, mutect2, varscan2
- ALDH1B1 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100890885; called by muse, mutect2, varscan2
- ANKRD27 | c.3085G>A p.V1029M | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.107); catalogued as rs146818631; called by muse, mutect2, varscan2
- AQP4 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV101270482; called by muse, mutect2, varscan2
- ARHGAP45 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100490353; called by muse, mutect2, varscan2
- ATP6V1A | c.1518A>C p.K506N | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849791; called by muse, mutect2
- ATR | c.4847C>G p.S1616* | Nonsense Mutation (SNP) | VAF 18/128 reads (14%) | catalogued as COSV100637640, COSV63388805; called by muse, mutect2, varscan2
- BABAM2 | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV100567225; called by muse, mutect2, varscan2
- BAZ2A | c.2894C>T p.A965V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99464603; called by muse, mutect2, varscan2
- C11orf52 | c.16T>G p.C6G | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.675); catalogued as rs140110474, COSV53714831, COSV99585521; called by muse, mutect2, varscan2
- C14orf28 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100290037; called by muse, mutect2, varscan2
- C6 | c.919C>A p.H307N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV99666436; called by muse, mutect2, varscan2
- CAPRIN2 | c.1169G>T p.W390L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99195406; called by muse, mutect2, varscan2
- CBLIF | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs905392611, COSV99950731; called by muse, mutect2, varscan2
- CDH10 | c.1830C>A p.S610R | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100049914; called by muse, mutect2, varscan2
- CDON | c.3463G>T p.V1155L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99700502; called by muse, mutect2, varscan2
- CFAP47 | c.2660G>T p.W887L | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99934254; called by muse, mutect2, varscan2
- CFAP47 | c.5360A>T p.K1787I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.122); catalogued as COSV100544858; called by muse, mutect2, varscan2
- CHD9 | c.1421A>G p.H474R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs754553161, COSV101271859; called by muse, mutect2, varscan2
- CLCA4 | c.2499C>G p.I833M | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV100990989, COSV65283856; called by muse, mutect2
- CLEC1B | c.583T>A p.C195S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100045941; called by muse, mutect2, varscan2
- CLIC6 | c.1909A>G p.T637A (on ENST00000360731 / NM_001317009.2; = p.T619A on NM_053277.3) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100659109; called by muse, mutect2, varscan2
- CNGB3 | c.2111A>G p.E704G | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100181108; called by muse, mutect2
- COL16A1 | c.1142G>C p.G381A | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99593450; called by muse, mutect2, varscan2
- COL22A1 | c.2735C>A p.P912H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100276104, COSV57362005; called by muse, mutect2
- COLQ | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.996); catalogued as CM000129, COSV101081966; called by muse, mutect2, varscan2
- CPED1 | c.2224T>A p.W742R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100119901; called by muse, mutect2, varscan2
- CRISP3 | c.200C>T p.T67I (on ENST00000371159 / NM_001368123.1; = p.T49I on NM_006061.4) | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99538554; called by muse, mutect2, varscan2
- CSH2 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100400140; called by mutect2, varscan2
- CSMD3 | c.7982G>C p.G2661A (on ENST00000297405 / NM_001363185.1; = p.G2557A on NM_052900.3) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52360794, COSV99823330; called by muse, mutect2
- CUBN | c.1919A>T p.H640L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100912013; called by muse, mutect2, varscan2
- CYP26B1 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs142999899; called by muse, mutect2, varscan2
- DCAF4L2 | c.778A>T p.S260C | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV100150467; called by muse, mutect2, varscan2
- DLGAP5 | c.2172G>C p.M724I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55965290, COSV99903611; called by muse, mutect2, varscan2
- DNAH17 | c.10964C>G p.A3655G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101101319, COSV101102374; called by muse, mutect2, varscan2
- DNAH7 | c.7012C>G p.L2338V | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100413706; called by muse, mutect2, varscan2
- DUOX2 | c.3209C>G p.S1070W | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV101199538, COSV66533456; called by muse, mutect2, varscan2
- DZIP3 | c.2974G>A p.V992I | Missense Mutation (SNP) | VAF 174/312 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100847590; called by muse, mutect2, varscan2
- ECE1 | c.898A>T p.I300F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV99941332; called by muse, mutect2, varscan2
- EFTUD2 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101274512; called by muse, mutect2, varscan2
- EIF2AK3 | c.383G>A p.W128* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100303365; called by muse, mutect2, varscan2
- EIF2AK4 | c.2614G>C p.D872H | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99774001; called by muse, mutect2, varscan2
- EMSY | c.2819G>T p.R940L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV100595317, COSV58262362; called by muse, mutect2, varscan2
- F13A1 | c.572-1G>T p.X191_splice | Splice Site (SNP) | VAF 23/113 reads (20%) | catalogued as COSV99342073; called by muse, mutect2, varscan2
- FADS2 | c.1191C>G p.H397Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV99608375; called by muse, mutect2, varscan2
- FAM135B | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.153); catalogued as rs538422547, COSV50523174; called by muse, mutect2, varscan2
- FER1L6 | c.5557A>C p.I1853L | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV101205392; called by muse, mutect2, varscan2
- FGF12 | c.474C>G p.I158M (on ENST00000454309 / NM_021032.5; = p.I96M on NM_004113.6) | Missense Mutation (SNP) | VAF 73/321 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.355); catalogued as COSV53187618, COSV99278589; called by muse, varscan2
- FGL2 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs962390445, COSV99592081; called by muse, mutect2, varscan2
- FREM1 | c.1528T>C p.F510L | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.751); catalogued as COSV101083696; called by muse, mutect2, varscan2
- FRS2 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV100165685; called by muse, mutect2, varscan2
- FSHR | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.361); catalogued as COSV100436468; called by muse, mutect2, varscan2
- GAS6 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59856728; called by muse, mutect2
- GCA | c.579G>T p.R193S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99280400; called by muse, mutect2, varscan2
- GLS | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100289673; called by muse, mutect2, varscan2
- GPR155 | c.812T>A p.L271Q | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); catalogued as COSV99789646; called by muse, mutect2, varscan2
- HAPLN1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV99164527; called by muse, mutect2, varscan2
- HOXB5 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99494340; called by muse, mutect2, varscan2
- HPN | c.786C>A p.H262Q | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.772); catalogued as rs772252121, COSV99384807; called by muse, mutect2, varscan2
- IGFALS | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.02); catalogued as COSV99236331; called by mutect2, varscan2
- IL17C | c.120G>C p.E40D | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV99733109; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1940C>A p.T647K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100780682, COSV61160689; called by muse, mutect2, varscan2
- IL26 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.595); catalogued as COSV99970787; called by muse, mutect2, varscan2
- INCENP | c.1422dup p.R475Qfs*47 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | catalogued as rs1443723586; called by mutect2, pindel, varscan2
- IQUB | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100226694; called by muse, mutect2, varscan2
- KCNH7 | c.1325G>C p.R442P | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV59787248, COSV59805925; called by muse, mutect2, varscan2
- KLHL2 | c.635C>G p.T212S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.264); catalogued as COSV99899596; called by muse, mutect2, varscan2
- KPNA6 | c.1322C>A p.A441D | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101012430; called by muse, mutect2, varscan2
- LCE2C | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs768082821, COSV100909378; called by muse, mutect2, varscan2
- LHX5 | c.222C>A p.S74R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as COSV55664322, COSV99922358; called by muse, mutect2, varscan2
- LMNB2 | c.1461G>C p.Q487H | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100321910; called by muse, mutect2, varscan2
- LRP1B | c.5197A>G p.K1733E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as COSV101251691; called by muse, mutect2
- LSR | c.438C>A p.D146E | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100670337; called by muse, mutect2, varscan2
- LSR | c.439A>T p.N147Y | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV100670338; called by muse, mutect2, varscan2
- LTBP4 | c.2300G>C p.R767P (on ENST00000308370 / NM_001042544.1; = p.R730P on NM_003573.2) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52575302, COSV99180354; called by muse, mutect2, varscan2
- MAGEA1 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100756605; called by muse, mutect2, varscan2
- MAOA | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV100108564; called by muse, mutect2, varscan2
- MCTP1 | c.2066A>T p.E689V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100386126; called by muse, mutect2
- MCTP1 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100386132; called by muse, mutect2
- MDGA2 | c.1963G>C p.G655R (on ENST00000399232 / NM_001113498.2; = p.G357R on NM_182830.4) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV100636294, COSV99050479; called by muse, mutect2, varscan2
- MELTF | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144478887; called by muse, mutect2, varscan2
- MIPOL1 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs1441700644, COSV100538037; called by muse, mutect2, varscan2
- MNAT1 | c.171C>A p.N57K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV99709698; called by muse, mutect2, varscan2
- MUC17 | c.11288C>A p.T3763K | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100071421; called by muse, mutect2, varscan2
- MYH2 | c.1973G>A p.R658K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.183); catalogued as COSV99819173; called by muse, mutect2, varscan2
- MYLK | c.5563T>C p.F1855L | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100658455; called by muse, mutect2, varscan2
- NAV3 | c.3878C>T p.S1293F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99886611, COSV99891195; called by muse, mutect2, varscan2
- NDN | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); catalogued as rs769908982, COSV100086198; called by muse, mutect2
- NELL1 | c.1786+2T>A p.X596_splice | Splice Site (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100118639; called by muse, mutect2, varscan2
- NOS2 | c.3181C>T p.R1061W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs200470759, COSV58221934, COSV58222238; called by muse, mutect2, varscan2
- NOX4 | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV99629444; called by muse, mutect2, varscan2
- NPAS1 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV101463918; called by muse, mutect2, varscan2
- ODF1 | c.741G>C p.K247N | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as COSV53433440, COSV99573977; called by muse, mutect2, varscan2
- OR10A5 | c.717C>A p.F239L | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100203364, COSV55055055; called by muse, mutect2, varscan2
- OR10K2 | c.562G>C p.A188P | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100149371, COSV59221690; called by muse, mutect2, varscan2
- OR1C1 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68715475; called by muse, mutect2, varscan2
- OR2A5 | c.579G>T p.W193C | Missense Mutation (SNP) | VAF 95/348 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV101278656, COSV101278886; called by muse, mutect2, varscan2
- OR52I2 | c.197T>C p.I66T | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1446503431, COSV100442820; called by muse, mutect2, varscan2
- OR56A1 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV100360386; called by muse, mutect2, varscan2
- OTOF | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV99716394; called by muse, mutect2, varscan2
- OTOGL | c.814C>T p.Q272* (on ENST00000547103; = p.Q263* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as rs1272784857, COSV101509012; called by muse, mutect2
- P2RY10 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV99408927; called by muse, mutect2, varscan2
- PAPLN | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs762361950, COSV99388966, COSV99389802; called by muse, mutect2, varscan2
- PCDH10 | c.2530C>T p.R844W | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.65); catalogued as COSV52087916; called by muse, mutect2, varscan2
- PCDH7 | c.2948T>C p.V983A | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.292); catalogued as COSV100687430; called by muse, mutect2, varscan2
- PCDHGB1 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as COSV53920479, COSV99529688; called by muse, mutect2, varscan2
- PIK3R2 | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.281); catalogued as COSV55849291, COSV99717158; called by muse, varscan2
- PIN4 | c.225A>C p.K75N (on ENST00000664196; = p.K50N on NM_006223.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV99512409; called by muse, mutect2, varscan2
- PIP4P2 | c.487-2A>T p.X163_splice | Splice Site (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99575118; called by muse, mutect2, varscan2
- PLCL2 | c.1776G>T p.M592I (on ENST00000615277 / NM_001144382.2; = p.M466I on NM_015184.5) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV67622100; called by muse, mutect2, varscan2
- PLIN3 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99701418; called by muse, mutect2, varscan2
- PREX2 | c.4766C>A p.S1589Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.275); catalogued as COSV55801640, COSV99904683; called by muse, mutect2
- PSPC1 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100142128; called by muse, mutect2, varscan2
- PTPRC | c.2042A>G p.N681S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770877340, COSV100722084; called by muse, mutect2, varscan2
- PTPRS | c.3577A>T p.R1193W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99508908; called by muse, mutect2, varscan2
- RB1 | c.2224del p.V742Ffs*2 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as CD058086, COSV57306946; called by mutect2, pindel, varscan2
- REN | c.800G>A p.W267* | Nonsense Mutation (SNP) | VAF 44/107 reads (41%) | catalogued as COSV99689385; called by muse, mutect2, varscan2
- RICTOR | c.1696A>G p.K566E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.06); catalogued as COSV99704269; called by muse, mutect2, varscan2
- RPAP1 | c.2653G>T p.A885S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.264); catalogued as COSV100426891; called by muse, mutect2, varscan2
- RUFY3 | c.582C>G p.Y194* | Nonsense Mutation (SNP) | VAF 27/154 reads (18%) | catalogued as COSV56913919, COSV99886734; called by muse, mutect2, varscan2
- SBSPON | c.321C>A p.N107K | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52075774, COSV99817285; called by muse, mutect2, varscan2
- SEC16B | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as COSV100381194, COSV57626897; called by muse, mutect2, varscan2
- SELENOP | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs369054600; called by muse, mutect2, varscan2
- SIDT2 | c.1991T>C p.I664T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV99637062; called by muse, mutect2, varscan2
- SIGLEC7 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99978409; called by muse, mutect2, varscan2
- SLC1A3 | c.921G>C p.M307I | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV99466940; called by muse, mutect2, varscan2
- SLC35F4 | c.1045T>A p.L349M (on ENST00000339762 / NM_001352015.2; = p.L313M on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100333495; called by muse, mutect2, varscan2
- SLCO1A2 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100261266; called by muse, mutect2
- SNAP91 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99534194; called by muse, mutect2, varscan2
- SNAP91 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99534200; called by muse, mutect2, varscan2
- SPATA31A1 | c.1435T>C p.C479R | Missense Mutation (SNP) | VAF 176/724 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV66533925; called by muse, mutect2, varscan2
- SPTA1 | c.6000C>A p.H2000Q | Missense Mutation (SNP) | VAF 116/477 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773921684, COSV100934150, COSV63758730; called by muse, mutect2, varscan2
- STAM | c.257C>G p.S86* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV101092161; called by muse, mutect2, varscan2
- STAT6 | c.1101G>C p.K367N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100273043; called by muse, mutect2, varscan2
- SYNE1 | c.25960A>T p.K8654* (on ENST00000367255 / NM_182961.4; = p.K8606* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 22/135 reads (16%) | catalogued as COSV99551912; called by muse, mutect2, varscan2
- SYNE1 | c.9117A>T p.K3039N (on ENST00000367255 / NM_182961.4; = p.K3046N on NM_033071.3) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99551921; called by muse, varscan2
- TACO1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV99366410; called by muse, mutect2, varscan2
- TGFB1 | c.350A>G p.H117R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1324057519, COSV54684407, COSV99699055; called by muse, mutect2, varscan2
- TMEM132D | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV101396153; called by muse, mutect2, varscan2
- TNNT3 | c.434A>T p.K145M (on ENST00000397301 / NM_001367846.1; = p.K134M on NM_006757.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV99547860; called by muse, mutect2, varscan2
- TNXB | c.8826C>G p.N2942K (on ENST00000647633; = p.N2695K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.709); catalogued as COSV100925745; called by muse, mutect2, varscan2
- TRDN | c.21A>T p.E7D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100520752; called by muse, mutect2
- TRHR | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs753608641, COSV100304628; called by muse, mutect2, varscan2
- TRPS1 | c.725A>T p.H242L (on ENST00000220888 / NM_001330599.2; = p.H255L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99628128; called by muse, mutect2, varscan2
- TSHZ2 | c.1334C>A p.P445Q | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV100295220, COSV61588424; called by muse, mutect2, varscan2
- TTC5 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV51872185; called by muse, mutect2, varscan2
- TTN | c.24974C>T p.P8325L (on ENST00000591111; = p.P7398L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | PolyPhen possibly damaging (0.873); catalogued as COSV100592539; called by muse, mutect2, varscan2
- UEVLD | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100260773; called by muse, mutect2, varscan2
- USP29 | c.2116G>C p.D706H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99038813; called by muse, mutect2, varscan2
- USP33 | c.987A>T p.R329S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100656998; called by muse, mutect2, varscan2
- USP6 | c.2873T>A p.V958E | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as rs1480520470, COSV100002932; called by muse, mutect2, varscan2
- VAC14 | c.486+1G>A p.X162_splice | Splice Site (SNP) | VAF 33/190 reads (17%) | catalogued as COSV99934099; called by muse, mutect2, varscan2
- WDFY3 | c.9478T>C p.S3160P | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV99881786; called by muse, mutect2, varscan2
- WDR17 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV54572370, COSV99706644; called by muse, mutect2, varscan2
- WWP1 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as COSV55357498; called by muse, mutect2
- XYLT2 | c.2537C>G p.S846C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50022455, COSV99190529; called by muse, mutect2, varscan2
- ZFHX3 | c.4694A>G p.N1565S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs572518232; called by muse, mutect2, varscan2
- ZFP3 | c.545C>G p.S182* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100603665, COSV59584445; called by muse, mutect2, varscan2
- ZNF134 | c.857G>T p.R286M | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV101270696; called by muse, mutect2, varscan2
- ZNF292 | c.5278G>C p.E1760Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); catalogued as rs1482487408, COSV100369676; called by muse, mutect2, varscan2
- ZNF343 | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV53854102, COSV99601201; called by muse, mutect2, varscan2
- ZNF439 | c.900T>A p.C300* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100397352; called by muse, mutect2, varscan2
- ZNF671 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100234828; called by muse, mutect2, varscan2
- ZNF804A | c.1765T>C p.W589R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV100166247; called by muse, mutect2, varscan2
- ZNF831 | c.1340C>A p.T447N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1178207579, COSV100925742; called by muse, mutect2, varscan2
- EXOSC9 | c.650del p.M217Rfs*6 | Frame Shift Del (DEL) | VAF 34/150 reads (23%) | called by mutect2, pindel, varscan2
- HMGCLL1 | c.527_529del p.S176_E177delins* | Nonsense Mutation (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- IGHG2 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 203/460 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- IRAK1 | c.923del p.P308Hfs*45 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | called by mutect2, pindel, varscan2
- MTMR6 | c.1199dup p.E402Gfs*15 | Frame Shift Ins (INS) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- NOMO3 | c.723A>T p.L241F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.054); called by mutect2, varscan2
- PRAMEF20 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 115/326 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC34A1 | c.658del p.A220Pfs*66 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- USP34 | c.238_241del p.Q80Ffs*10 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- ZNF449 | c.1221_1222del p.Y407* | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | called by pindel, varscan2
- ADGRV1 | c.17928C>A p.V5976= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV101315425; called by muse, mutect2, varscan2
- ADRA1A | c.1267C>A p.R423= | Silent (SNP) | VAF 53/163 reads (33%) | catalogued as COSV99369834; called by muse, mutect2, varscan2
- ALX4 | c.1014C>G p.P338= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100240864, COSV100241001; called by muse, mutect2, varscan2
- CAVIN4 | c.942C>A p.L314= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as COSV100293097; called by muse, mutect2, varscan2
- CETN1 | c.252C>T p.I84= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100511193; called by muse, mutect2, varscan2
- CHRNA4 | c.1755C>T p.F585= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV64718483; called by muse, mutect2, varscan2
- CLMN | c.1287G>A p.E429= | Silent (SNP) | VAF 96/151 reads (64%) | catalogued as COSV100111978; called by muse, mutect2, varscan2
- COL5A2 | c.1569T>C p.A523= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100879977; called by muse, mutect2, varscan2
- CYTH3 | c.759C>T p.D253= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1056986105, COSV63437370; called by muse, mutect2, varscan2
- DALRD3 | c.553A>C p.R185= (on ENST00000341949 / NM_001009996.3; = p.R18= on NM_018114.5) | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100482729; called by muse, mutect2, varscan2
- DENND1B | c.1005T>A p.A335= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as COSV52473571, COSV99343687; called by muse, mutect2, varscan2
- DNAH5 | c.7665C>T p.T2555= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as rs1257235664, COSV99444487; called by muse, mutect2, varscan2
- DSG2 | c.2340G>T p.A780= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs375539435, COSV99853325; ClinVar: likely benign; called by muse, mutect2, varscan2
- GIMAP2 | c.468G>T p.L156= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99785191; called by muse, mutect2
- H4C11 | c.246C>A p.V82= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100747931, COSV100748007; called by muse, mutect2, varscan2
- IGKV1-17 | c.96C>T p.S32= | Silent (SNP) | VAF 86/300 reads (29%) | called by muse, mutect2, varscan2
- IGSF22 | c.1290G>A p.V430= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV100079071; called by muse, mutect2
- INTU | c.1131T>G p.A377= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99611406; called by muse, mutect2, varscan2
- KCNA5 | c.412C>T p.L138= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99363580; called by muse, mutect2, varscan2
- KIF23 | c.2259A>G p.P753= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV99531807; called by muse, mutect2
- MIGA1 | c.210G>A p.P70= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs989499404, COSV66223602; called by muse, mutect2, varscan2
- MSI2 | c.357G>C p.A119= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV52362694, COSV99401557; called by muse, mutect2, varscan2
- MYH15 | c.2172A>T p.R724= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV99842116; called by muse, mutect2, varscan2
- NCKAP1L | c.2592T>A p.I864= | Silent (SNP) | VAF 46/172 reads (27%) | catalogued as COSV99514375; called by muse, mutect2, varscan2
- NPAS2 | c.2427G>A p.R809= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100175688; called by muse, mutect2, varscan2
- OR2F2 | c.762A>T p.T254= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV101283792; called by muse, mutect2, varscan2
- ORC3 | c.1416T>C p.L472= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100005571; called by muse, mutect2, varscan2
- P2RY6 | c.18C>T p.G6= | Silent (SNP) | VAF 27/209 reads (13%) | catalogued as COSV100573835; called by muse, mutect2, varscan2
- PEX2 | c.66A>T p.A22= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV100824686; called by muse, mutect2, varscan2
- POR | c.1296C>T p.A432= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV100115448; called by muse, mutect2, varscan2
- PRPF31 | c.1284G>A p.L428= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100319851; called by muse, mutect2, varscan2
- PTCH1 | c.1404C>G p.A468= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100107395; called by muse, mutect2, varscan2
- PTP4A3 | c.60C>A p.L20= | Silent (SNP) | VAF 37/210 reads (18%) | catalogued as COSV100267044, COSV61472081; called by muse, mutect2, varscan2
- SLC35A4 | c.822C>G p.G274= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100021068; called by muse, mutect2, varscan2
- SPATA19 | c.399G>A p.E133= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100141010; called by muse, mutect2
- TNFAIP8L1 | c.202C>T p.L68= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100542337; called by muse, mutect2, varscan2
- TTYH2 | c.177C>T p.N59= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs1488365297, COSV99482781; called by muse, mutect2, varscan2
- UBQLN2 | c.1542G>T p.G514= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100592616; called by muse, mutect2, varscan2
- WDR90 | c.1518C>T p.D506= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as rs376072128; called by muse, mutect2, varscan2
- ZC3H18 | c.1857C>T p.I619= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV56325500; called by muse, mutect2, varscan2
- ZNF189 | c.1485G>T p.R495= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99407077; called by muse, mutect2, varscan2
- ZNF25 | c.1290G>A p.E430= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV100224498; called by muse, mutect2, varscan2
- ZNF280D | c.2752T>C p.L918= | Silent (SNP) | VAF 66/125 reads (53%) | catalogued as COSV99974024; called by muse, mutect2, varscan2
- ZNF398 | c.270C>T p.N90= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as COSV100246805; called by muse, mutect2, varscan2
- ZNF530 | c.759C>G p.G253= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV100252364; called by muse, mutect2, varscan2
- ADAR | c.-983A>G | 5'UTR (SNP) | VAF 13/126 reads (10%) | called by muse, varscan2
- ADAR | c.-984G>T | 5'UTR (SNP) | VAF 14/128 reads (11%) | called by muse, varscan2
- ADARB2 | c.101-147677C>A | Intron (SNP) | VAF 20/94 reads (21%) | catalogued as COSV101184471; called by muse, mutect2
- HTR3E | c.68-15C>G | Intron (SNP) | VAF 48/536 reads (9%) | catalogued as rs202036764, COSV100093624, COSV58949485; called by muse, mutect2
- MFSD4B | c.*484G>T | 3'UTR (SNP) | VAF 38/146 reads (26%) | catalogued as COSV100920538; called by muse, mutect2, varscan2
- MIR20B | n.48T>C | RNA (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- NEBL | c.164+46533G>A | Intron (SNP) | VAF 47/196 reads (24%) | catalogued as rs1359524874, COSV101008647, COSV65797870; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23166359 C>A | 3'Flank (SNP) | VAF 8/60 reads (13%) | called by muse, varscan2
- SNORD115-22 | n.79T>G | RNA (SNP) | VAF 47/310 reads (15%) | catalogued as rs775057141; called by muse, mutect2, varscan2
- SNORD116-3 | n.27A>T | RNA (SNP) | VAF 54/258 reads (21%) | called by muse, varscan2
- TBCE | c.371+4898G>T | Intron (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100782963, COSV64006783; called by muse, mutect2, varscan2
- XIRP2 | c.*662G>A | 3'UTR (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99737940; called by muse, mutect2, varscan2
- ZNF783 | c.802+3577T>C | Intron (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100954099; called by muse, mutect2, varscan2
